Somatic mutation profile of tumor specimen 0DMBM7 from CCDI case PBCAFN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,962 days).
Specimen 0DMBM7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29010d6a-81a6-4b27-8c19-f4cb3a72b730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/539a79d7-823e-4ccd-a788-09ca34c2fa74

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.2696C>G p.P899R | Missense Mutation (SNP) | VAF 186/454 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV59326379, COSV59339654; called by muse, varscan2
- SZT2 | c.9122A>C p.H3041P (on ENST00000634258 / NM_001365999.1; = p.H2984P on NM_015284.4) | Missense Mutation (SNP) | VAF 230/520 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100981245; called by muse, varscan2
- TTC34 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 224/520 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1168859131; called by muse, varscan2
- DOCK6 | c.5791C>G p.Q1931E | Missense Mutation (SNP) | VAF 324/686 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SLC28A2 | c.1894T>C p.S632P | Missense Mutation (SNP) | VAF 400/832 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.439); called by muse, varscan2
- MAX | c.295+496A>G | Intron (SNP) | VAF 190/444 reads (43%) | called by muse, varscan2
